Somatic mutation profile of tumor specimen 0DZ4NV from CCDI case PBCAIM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 5.0 years (1,832 days).
Specimen 0DZ4NV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c10268d-c23d-4636-9460-da555387902e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZ4M7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e1cbbf1-1e3c-4c91-98af-257ff5db8e83

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CT83 | c.46A>T p.I16F | Missense Mutation (SNP) | VAF 360/787 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, varscan2
- ELMO1 | c.2162A>T p.D721V | Missense Mutation (SNP) | VAF 76/737 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, varscan2
- PREX2 | c.1329C>T p.I443= | Silent (SNP) | VAF 44/444 reads (10%) | catalogued as COSV99907241; called by muse, varscan2
